Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A020, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A020-01A (Primary Tumor).

Sample ID #:

This is an invasive rectal carcinoma, in this case with medium-grade differentiation, of the mucinous type (G 2), with infiltration of all layers of the wall (pT3), lymph vessel invasions (L1), a lymph node metastasis (pN1, 1 of 12), free resection margins in the region of the mucosa and a free ligature area.

ICD-0-3

carcinoma, mucinous 8480/3

Site: Rectum C20.9 per 3/21/11

Source: NCI Genomic Data Commons file 9ea195fd-78e2-4dd9-b9fb-d5730c5cabb1 (TCGA-AG-A020.24622F29-0BFC-4E7B-B395-BCB5A02F44DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).